Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA69, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA69-01A (Primary Tumor).

Collect date:

CHF ICD O-3
Adenocarcinoma NOS 8140/3
rate
Carcinoma, undifferentiated NOS 8620/3
Site: Gastroesophageal junction C16.0
7/3/2014

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1- "Product of esophagogastrrectomy":

Undifferentiated carcinoma associated with moderately differentiated adenocarcinoma of gastroesophageal junction (measuring 12.6 cm), infiltrating up to perigastric adipose tissue.

Note: Most of the tumor is located in the stomach, extending to the esophagus.

Presence of foci of Angiolymphatic vascular invasion.

Surgical margins free of neoplasia.

Metastases in six lymph nodes (6/37): one from chain 2, three from chain 3, two from chain 9 (with Extranodal invasion).

2 - "Greater omentum":

Absence of neoplasia.

3 - "Esophageal margin":

Absence of neoplasia.

Note: See immunohistochemical study

Source: NCI Genomic Data Commons file 86b829cb-50a4-4342-b065-1e2917bfcad0 (TCGA-VQ-AA69.3B8DBFF7-A3D6-42AF-B721-919D0B2E88E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).